Surgical pathology report (de-identified scan), TCGA case TCGA-DU-6397, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site Henry Ford Hospital, specimen TCGA-DU-6397-01A (Primary Tumor).

Anatomic Pathology/Cytology Document State: (version)
Update Date/Time:
Final 1

Patient Name: MRN: Service Date/Time:
DOB/Age/Gender: Male Provider:
Location: Responsible Staff:

PATH.NO:
NAME: MED. REC. NO:
AGE/SEX: M DOB: SURGERY DATE:
RECEIVE DATE:
PHYSICIAN:
COPY TO:
UPDATE REPORT - SEE SPECIAL STAIN REPORT

PATHOLOGICAL DIAGNOSIS:
RIGHT TEMPORAL LOBE: ANAPLASTIC OLIGODENDROGLIOMA.
SPECIAL STAIN REPORT: MIB-1 LABELLING INDEX 20%

Operation/Specimen: UPDATED REPORT
Clinical History and Pre-Op Dx:
GROSS PATHOLOGY:
A. One tissue fragment, 0.5 x 0.4 cm. Frozen section diagnosis:
Glioma in #1 and 2.
B.
SPECIMEN: None provided.
FIXATIVE: Not given.
GENERAL: Four, irregularly-shaped, tan-red to golden yellow
portions of brain tissue ranging from .5 to 1.0 x 0.5 x
0.3 cm.
SECTIONS: X1 - all submitted.

MICROSCOPIC: Sections show an oligodendroglioma with hypercellularity,
frequent nuclear pleomorphism and mitotic figures. Fibrovascular
networks are prominent with marked endothelial hyperplasia. Tumor
necrosis is not seen.

TISSUE COMMITTEE CODE: TC1.
BILLING CODES:

100-0-3
Oligodendroglioma grade III
9451/3
Site Brain, supratentorial^{NH}
C71.0
Brain, frontal lobe
C71.1
JW 7/30/13

Primary Tumor Size Discrepancy		✓

Source: NCI Genomic Data Commons file 59a093ff-1498-4db5-9449-d9d6774f6e23 (TCGA-DU-6397.54C5D9F8-8737-49DA-81CF-F9A95B0DB456.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).